Gene-level copy-number profile of tumor specimen HCM-BROD-0254-C49-86N from HCMI case HCM-BROD-0254-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 11.9 years (4,358 days).
Specimen HCM-BROD-0254-C49-86N: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 15.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6fbbd246-2ed0-4120-901f-6de3537936e9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0254-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/5306d81f-930b-438c-98d8-e9c55307f124

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 11; copy number 2: 3,580; copy number 3: 23,886; copy number 4: 6,116; copy number 5: 11,558; copy number 6: 12,518; copy number 7: 992; copy number 8: 92; copy number 9: 45; copy number 10: 60; copy number 11: 11; copy number 12: 9; copy number 13: 2; copy number 16: 5; copy number 17: 1; copy number 24: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,225 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–145,281,462, 65 genes, copy number 10–11 (broad region; genes not listed).
- chr2:23,330,664–25,673,647, 54 genes, copy number 7–8: AC012506.1, AC012506.3, AC012506.2, AC012506.4, KLHL29, AC011239.1, AC011239.2, AC009242.1, ATAD2B, PGAM1P6, RPS13P4, UBXN2A, SDHCP3, RN7SL610P, MFSD2B, WDCP, RNU6-370P, FKBP1B, SF3B6, FAM228B, TP53I3, PFN4, AC008073.3, AC008073.2, FAM228A, AC008073.1, ITSN2, AC009228.1, AC009228.2, HMGN2P20, RPL36AP13, NCOA1, RNA5SP88, RNU6-936P, PTRHD1, CENPO, ADCY3, AC012073.1, DNAJC27, RPS13P5, SNORD14, DNAJC27-AS1, AC013267.1, Y_RNA, EFR3B, RN7SL856P, SUCLA2P3, POMC, LINC01381, DNMT3A, MIR1301, ARNILA, DTNB, DTNB-AS1.
- chr2:222,199,887–236,131,800, 243 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr5:45,254,948–45,696,498, 3 genes, copy number 7: HCN1, AC117529.2, AC117529.1.
- chr9:32,820,261–35,149,184, 116 genes, copy number 7 (broad region; genes not listed).
- chr9:42,830,337–64,889,063, 107 genes, copy number 7–24 (broad region; genes not listed).
- chr9:65,282,101–65,285,209, 1 gene, copy number 8: FOXD4L5.
- chr9:66,022,661–66,113,085, 7 genes, copy number 9–16 (within-gene range 7–16): GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1.
- chr13:18,467,172–40,611,127, 419 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr14:18,333,726–18,637,421, 11 genes, copy number 7–17: CR383658.1, CR383658.2, BNIP3P6, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12.
- chr14:18,889,084–19,003,752, 8 genes, copy number 10–12: NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P.
- chr14:19,124,807–19,700,650, 34 genes, copy number 7: AL589743.3, NBEAP5, AL589182.2, OR11H13P, AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1, DUXAP10, BMS1P17, AL929602.1, LINC01297, GRAMD4P3, POTEG, AL512624.2, RNU6-1268P, MED15P6, NF1P4, AL512310.11, AL512624.1, NF1P11, AL512310.3, AL512310.10, AL512310.8, AL512310.4, AL512310.5, AL512310.6, AL512310.9, AL512310.7, AL512310.2, ARHGAP42P4, AL512310.1.
- chr15:19,878,555–19,899,559, 3 genes, copy number 8: AC138701.1, RNU6-978P, AC138701.2.
- chr16:46,469,341–46,831,180, 15 genes, copy number 7: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87.
- chr21:7,744,962–15,880,069, 138 genes, copy number 7–8 (broad region; genes not listed).
- chr21:16,035,413–16,035,509, 1 gene, copy number 7: RNU6-426P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
